Somatic mutation profile of tumor specimen HCM-CSHL-0247-C18-01A (aliquot HCM-CSHL-0247-C18-01A-21D-A78T-36) from HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19219882-62ea-494b-912e-12cb5303a404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0247-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0247-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daa2d1af-23b8-47f9-8dd6-f8f9506a2c73

The open-access MAF lists 144 somatic variants for this specimen: 98 protein-altering or splice-affecting, 31 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 31, Nonsense Mutation 7, Intron 5, 5'UTR 4, 3'UTR 3, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 80/87 reads (92%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 60/114 reads (53%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 73/182 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 63/107 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 719/781 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 263/583 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALPK3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 188/225 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV51940688; called by muse, mutect2, varscan2
- AP1M2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs761767257; called by muse, mutect2, varscan2
- ASAP1 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 147/343 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1365555616; called by muse, mutect2, varscan2
- CACNA1A | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs756562814, COSV64200832, COSV64211473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAP2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs200521747, COSV57731947; called by muse, mutect2, varscan2
- CDH23 | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs760927863, COSV56477037; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CERS2 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 77/481 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1284685209, COSV99644932; called by muse, mutect2, varscan2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 162/541 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by muse, mutect2, varscan2
- COL4A2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 68/465 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773576081; called by muse, mutect2, varscan2
- COMMD1 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61273397; called by muse, mutect2, varscan2
- CPB1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs150860615, COSV99294138; called by muse, mutect2, varscan2
- CSMD3 | c.5836C>A p.R1946S (on ENST00000297405 / NM_001363185.1; = p.R1842S on NM_052900.3) | Missense Mutation (SNP) | VAF 167/412 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs377290204; called by muse, mutect2, varscan2
- CUBN | c.5387T>C p.V1796A | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1347845858; called by muse, mutect2, varscan2
- DIPK1B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 157/422 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770330516, COSV63038081; called by muse, mutect2, varscan2
- EHD3 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59031523; called by muse, mutect2, varscan2
- EIF2B5 | c.1630G>A p.E544K (on ENST00000647909; = p.E536K on NM_003907.3) | Missense Mutation (SNP) | VAF 170/367 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV56605595; called by muse, mutect2, varscan2
- ERCC6L2 | c.1939T>C p.Y647H | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs546945597; called by muse, mutect2, varscan2
- GLI3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 330/1086 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs1296035859, COSV67890481; called by muse, varscan2
- GLI3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 756/1222 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs755227076, COSV67887250; ClinVar: uncertain significance; called by muse, varscan2
- GRM3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs112122758, COSV100862026, COSV64478495; called by muse, mutect2, varscan2
- HAPLN4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52269389; called by muse, mutect2, varscan2
- HLA-DOA | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs200140467; called by muse, mutect2
- HPCAL1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV57145974; called by muse, mutect2, varscan2
- HSD17B6 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs370898544; called by muse, mutect2, varscan2
- IRX5 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1400582762; called by muse, mutect2
- JAG2 | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 150/270 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs1216756119, COSV59307824; called by muse, mutect2, varscan2
- MNDA | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1329858284; called by muse, mutect2, varscan2
- MSLNL | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765899968, COSV53498896; called by muse, mutect2, varscan2
- NKX3-2 | c.468C>T p.G156= | Splice Region (SNP) | VAF 80/310 reads (26%) | catalogued as rs1382050386, COSV66712053; called by muse, mutect2, varscan2
- NLRC5 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs866090118, COSV52660803; called by muse, mutect2
- NOL6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 164/371 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756516749; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 97/447 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.803G>A p.R268H (on ENST00000259318 / NM_001136562.3; = p.R499H on NM_007203.5) | Missense Mutation (SNP) | VAF 128/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368590919; called by muse, varscan2
- PCDHA12 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 190/637 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs781787046, COSV56485542; called by muse, mutect2, varscan2
- PCDHGA6 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 342/573 reads (60%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); catalogued as rs919176873, COSV53913907; called by muse, mutect2, varscan2
- RIMBP2 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs763832408; called by muse, mutect2, varscan2
- RNF2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs1335456103, COSV62279097; called by muse, mutect2, varscan2
- RPH3A | c.670C>T p.P224S (on ENST00000389385 / NM_001143854.2; = p.P220S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs771368523; called by muse, mutect2, varscan2
- SCG2 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV100544644, COSV59539409; called by muse, mutect2
- SERPINB2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922692149, COSV55091465; called by muse, mutect2, varscan2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 87/105 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SLC22A8 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 231/528 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as rs755584994; called by muse, mutect2, varscan2
- SLC6A2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 234/590 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776659407, COSV54923884; called by muse, mutect2, varscan2
- SOX9 | c.1261_1267dup p.F423* | Frame Shift Ins (INS) | VAF 124/171 reads (73%) | catalogued as COSV55427921; called by mutect2, varscan2
- SST | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as rs763961867, COSV55030751; called by muse, mutect2, varscan2
- TNXB | c.5065G>A p.G1689S (on ENST00000647633; = p.G1442S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/401 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762480960; called by muse, mutect2, varscan2
- UBAP1L | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 122/140 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs933188149; called by muse, mutect2, varscan2
- WDR7 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 158/180 reads (88%) | SIFT tolerated (0.64); PolyPhen benign (0.181); catalogued as rs750926404; called by muse, mutect2, varscan2
- ZNF251 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 116/235 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200114017; called by muse, mutect2, varscan2
- ACSM2A | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.051); called by muse, mutect2
- APC | c.3209del p.N1070Ifs*56 | Frame Shift Del (DEL) | VAF 90/328 reads (27%) | called by mutect2, pindel, varscan2
- CAMK2G | c.1437del p.F479Lfs*17 (on ENST00000423381 / NM_001367518.1; = p.F416Lfs*17 on NM_001222.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 96/233 reads (41%) | called by mutect2, pindel, varscan2
- CCDC141 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CDHR5 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- CLASP2 | c.4067C>G p.A1356G (on ENST00000359576; = p.A1355G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- COL6A5 | c.2828A>G p.N943S | Missense Mutation (SNP) | VAF 153/416 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DACT2 | c.2024dup p.S676Vfs*13 | Frame Shift Ins (INS) | VAF 73/187 reads (39%) | called by mutect2, pindel, varscan2
- EBF3 | c.1438C>A p.Q480K (on ENST00000355311 / NM_001375392.1; = p.Q471K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- EIF2B2 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 132/444 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- EPHA5 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 141/170 reads (83%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM217B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 342/531 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FAM72B | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 358/605 reads (59%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GNG11 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GRM1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ | c.2752T>A p.F918I | Missense Mutation (SNP) | VAF 195/207 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HTR3A | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 162/402 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); called by muse, varscan2
- INHBA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 371/607 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGA9 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 159/374 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITGB3 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 326/753 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- L3MBTL4 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 89/116 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAP1A | c.6785A>G p.E2262G | Missense Mutation (SNP) | VAF 298/353 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NKTR | c.3205A>G p.K1069E | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51F1 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PDS5B | c.2475A>C p.K825N | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PPP1CB | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 129/154 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRICKLE1 | c.1074C>A p.Y358* | Nonsense Mutation (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- PXDNL | c.3256T>A p.F1086I | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A4 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 124/479 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC35D3 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- SLIT1 | c.2627G>A p.W876* | Nonsense Mutation (SNP) | VAF 71/235 reads (30%) | called by muse, mutect2, varscan2
- SMG1 | c.9077T>A p.L3026Q | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SSBP4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SSC5D | c.2251T>C p.S751P | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STK31 | c.1961A>T p.E654V | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX51 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TOGARAM1 | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 149/219 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- USP48 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 155/194 reads (80%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UST | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 112/256 reads (44%) | called by muse, mutect2
- WDR6 | c.3111_3113dup p.E1037_Y1038ins* | Nonsense Mutation (INS) | VAF 131/349 reads (38%) | called by mutect2, pindel, varscan2
- ABCG4 | c.78C>T p.D26= | Silent (SNP) | VAF 169/383 reads (44%) | catalogued as rs373824430; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1791G>A p.G597= | Silent (SNP) | VAF 130/324 reads (40%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1071C>T p.N357= | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as rs937679166; called by muse, mutect2, varscan2
- APOBEC3F | c.708C>T p.G236= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as COSV57910186; called by muse, mutect2
- CTNNA2 | c.351G>A p.S117= | Silent (SNP) | VAF 150/376 reads (40%) | catalogued as rs201020471, COSV63548922; called by muse, mutect2, varscan2
- CYP2D6 | c.264C>T p.R88= | Silent (SNP) | VAF 370/1377 reads (27%) | catalogued as rs1230147351; called by muse, mutect2, varscan2
- DAB2 | c.1386C>T p.P462= | Silent (SNP) | VAF 68/234 reads (29%) | catalogued as rs1232950773, COSV57917425; called by muse, mutect2, varscan2
- DPP10 | c.1321C>T p.L441= | Silent (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- FAM161A | c.90C>T p.Y30= | Silent (SNP) | VAF 275/625 reads (44%) | called by muse, mutect2, varscan2
- FAT3 | c.11919G>A p.T3973= | Silent (SNP) | VAF 182/432 reads (42%) | catalogued as rs898299684, COSV53101021; called by muse, mutect2, varscan2
- FOXO1 | c.1746C>T p.S582= | Silent (SNP) | VAF 156/227 reads (69%) | called by muse, mutect2, varscan2
- GAB4 | c.72G>A p.S24= | Silent (SNP) | VAF 129/289 reads (45%) | catalogued as rs1182743180; called by muse, mutect2, varscan2
- GALNT14 | c.1587C>T p.N529= | Silent (SNP) | VAF 129/302 reads (43%) | catalogued as rs145219116; called by muse, mutect2, varscan2
- GATA5 | c.675G>A p.P225= | Silent (SNP) | VAF 231/748 reads (31%) | catalogued as rs144082730; called by muse, mutect2, varscan2
- GGT6 | c.780C>T p.S260= (on ENST00000574154 / NM_001122890.3; = p.S228= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/228 reads (48%) | catalogued as rs768266892, COSV99626686; called by muse, mutect2, varscan2
- HECW2 | c.1914G>A p.L638= | Silent (SNP) | VAF 36/64 reads (56%) | catalogued as COSV53651191; called by muse, mutect2, varscan2
- KLHL4 | c.2040A>G p.G680= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- LMNB1 | c.1332C>T p.I444= | Silent (SNP) | VAF 135/252 reads (54%) | catalogued as rs779989576; called by muse, mutect2, varscan2
- MC2R | c.504C>T p.F168= | Silent (SNP) | VAF 139/168 reads (83%) | called by muse, mutect2, varscan2
- MESP1 | c.231C>T p.S77= | Silent (SNP) | VAF 97/118 reads (82%) | called by muse, mutect2, varscan2
- MYT1L | c.816C>T p.H272= | Silent (SNP) | VAF 134/280 reads (48%) | catalogued as rs751168400, COSV67728872; called by muse, mutect2, varscan2
- NBEA | c.7884A>G p.R2628= | Silent (SNP) | VAF 187/676 reads (28%) | catalogued as rs1408284485; called by muse, mutect2, varscan2
- NPL | c.324C>T p.I108= | Silent (SNP) | VAF 233/492 reads (47%) | catalogued as rs369901524; called by muse, mutect2, varscan2
- OCM2 | c.15C>T p.D5= | Silent (SNP) | VAF 82/352 reads (23%) | catalogued as rs762988500, COSV57535963; called by muse, varscan2
- PLEKHA4 | c.1126C>A p.R376= | Silent (SNP) | VAF 63/196 reads (32%) | called by muse, mutect2, varscan2
- PPT1 | c.363G>A p.R121= (on ENST00000433473; = p.R122= on NM_000310.4) | Silent (SNP) | VAF 244/294 reads (83%) | called by muse, mutect2, varscan2
- PROKR2 | c.420C>T p.Y140= | Silent (SNP) | VAF 87/290 reads (30%) | catalogued as rs199794008, CM085658; called by muse, mutect2, varscan2
- USP2 | c.705G>A p.T235= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs752095300, COSV52730776; called by muse, mutect2, varscan2
- VIP | c.258C>T p.F86= | Silent (SNP) | VAF 88/226 reads (39%) | catalogued as rs371797297; called by muse, mutect2, varscan2
- WDR13 | c.456G>A p.T152= | Silent (SNP) | VAF 185/227 reads (81%) | catalogued as rs1556993839; called by muse, mutect2, varscan2
- ZNF98 | c.870A>G p.G290= | Silent (SNP) | VAF 18/88 reads (20%) | called by mutect2, varscan2
- C9orf62 | n.511G>T | RNA (SNP) | VAF 104/224 reads (46%) | catalogued as rs1011518817; called by muse, mutect2, varscan2
- CFL2 | c.*1950T>G | 3'UTR (SNP) | VAF 50/422 reads (12%) | called by muse, mutect2, varscan2
- CGB8 | c.-12G>T | 5'UTR (SNP) | VAF 153/195 reads (78%) | catalogued as rs200172544; called by muse, mutect2, varscan2
- CPNE2 | c.928-520C>T | Intron (SNP) | VAF 95/276 reads (34%) | called by muse, mutect2, varscan2
- FSHB | c.-1G>A | 5'UTR (SNP) | VAF 155/357 reads (43%) | called by muse, mutect2, varscan2
- IKBKB | c.1516+42T>G | Intron (SNP) | VAF 170/356 reads (48%) | called by muse, mutect2, varscan2
- KIAA0513 | c.902+9G>A | Intron (SNP) | VAF 102/223 reads (46%) | catalogued as rs375448048; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.*186C>G | 3'UTR (SNP) | VAF 112/248 reads (45%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.-23G>A | 5'UTR (SNP) | VAF 212/498 reads (43%) | called by muse, mutect2, varscan2
- PLCG2 | c.2307+89C>A | Intron (SNP) | VAF 156/351 reads (44%) | called by muse, mutect2, varscan2
- PRDM9 | c.-34A>G | 5'UTR (SNP) | VAF 154/288 reads (53%) | called by muse, mutect2, varscan2
- SEMA4D | chr9:89376970 G>A | 3'Flank (SNP) | VAF 68/351 reads (19%) | called by muse, mutect2, varscan2
- SFXN5 | c.945+4098C>T | Intron (SNP) | VAF 96/255 reads (38%) | catalogued as rs1037813559; called by muse, mutect2, varscan2
- SP5 | chr2:170714278 C>T | 5'Flank (SNP) | VAF 50/407 reads (12%) | called by muse, mutect2, varscan2
- TMEM120A | c.*67C>T | 3'UTR (SNP) | VAF 133/203 reads (66%) | catalogued as rs782267943; called by muse, mutect2, varscan2
